Somatic mutation profile of tumor specimen 0DW745 from CCDI case PBCMUA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 9.4 years (3,446 days).
Specimen 0DW745: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 764c932a-9d4f-4e8b-b1ec-8004ef8757d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW72L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e3f7c68-d899-4b09-8b7e-6f61130863ae

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 36/630 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs759672856, COSV54224103; called by muse, mutect2
- MED16 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 20/626 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- PRRC2C | c.665G>A p.R222K (on ENST00000367742; = p.R220K on NM_015172.4) | Missense Mutation (SNP) | VAF 25/756 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.621); called by muse, mutect2
- FNIP1 | c.2274T>G p.S758= | Silent (SNP) | VAF 30/606 reads (5%) | called by muse, mutect2
- SORBS2 | c.-46+1273T>A | Intron (SNP) | VAF 42/990 reads (4%) | called by muse, mutect2
